Somatic mutation profile of tumor specimen MMRF_2335_1_BM_CD138pos (aliquot MMRF_2335_1_BM_CD138pos_T1_KHS5U_L11025) from MMRF case MMRF_2335, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.9 years (23,700 days).
Specimen MMRF_2335_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75588c39-6fef-4aa8-9bd4-caa8a692ba6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2335_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2335_1_PB_WBC_C2_KHS5U_L11026; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c394dad2-682b-4fc7-bbca-71d5cd89082c

The open-access MAF lists 132 somatic variants for this specimen: 48 protein-altering or splice-affecting, 26 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 42, Missense Mutation 39, Silent 26, Intron 9, Frame Shift Del 4, Nonsense Mutation 4, 3'Flank 3, 5'UTR 2, RNA 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 56/185 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ABCB11 | c.1685G>A p.G562D | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM081503; called by muse, mutect2, varscan2
- CACNA1D | c.1511G>A p.R504H (on ENST00000350061 / NM_001128840.3; = p.R524H on NM_000720.4) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.043); catalogued as COSV55449352; called by muse, mutect2, varscan2
- CLDN18 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 60/222 reads (27%) | catalogued as rs766241791, COSV59302461; called by muse, mutect2, varscan2
- COL22A1 | c.3472C>T p.P1158S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs974638459; called by muse, mutect2, varscan2
- FOCAD | c.1667G>C p.R556P | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1214748604; called by muse, mutect2, varscan2
- HMMR | c.1334A>T p.Y445F | Missense Mutation (SNP) | VAF 92/112 reads (82%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as rs867941837; called by muse, mutect2, varscan2
- IGHV2-70 | c.250_251del p.L84Efs*? | Frame Shift Del (DEL) | VAF 38/48 reads (79%) | catalogued as rs779095288; called by pindel, varscan2
- IGKV4-1 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs557782478; called by muse, mutect2, varscan2
- IGLV3-1 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as rs371362948; called by muse, mutect2
- IGLV3-1 | c.259A>G p.N87D | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs374619711; called by muse, mutect2
- KCNG1 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as rs1162689511, COSV65369582; called by muse, mutect2, varscan2
- KMT2E | c.3397T>C p.F1133L | Missense Mutation (SNP) | VAF 128/302 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as COSV57576560, COSV57576758; called by muse, mutect2, varscan2
- LINGO1 | c.1322C>T p.T441M | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as rs768903780, COSV62436392; called by muse, mutect2, varscan2
- LTB | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 189/395 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as rs571318566, COSV53001827, COSV53002251; called by muse, varscan2
- MCTP1 | c.1483G>A p.V495M | Missense Mutation (SNP) | VAF 147/544 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1450694472, COSV100386399; called by muse, mutect2, varscan2
- MORC2 | c.1463G>A p.R488Q (on ENST00000397641 / NM_001303256.3; = p.R426Q on NM_014941.3) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs750886983; called by muse, mutect2, varscan2
- NLRP12 | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.042); catalogued as rs765948822, COSV100145325, COSV60743430, COSV60753163; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | catalogued as rs755413956; called by mutect2, varscan2
- PCDHA2 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as rs371053543; called by muse, mutect2, varscan2
- PPP1R12B | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 153/332 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51789374; called by muse, mutect2
- REL | c.1786_1789del p.Q596Ifs*12 | Frame Shift Del (DEL) | VAF 43/106 reads (41%) | catalogued as rs748714005; called by mutect2, pindel, varscan2
- RTL1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as rs758575352; called by muse, mutect2, varscan2
- SDK2 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs760209315, COSV66180576; called by muse, mutect2, varscan2
- TREML2 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1199438193; called by muse, varscan2
- TUBGCP3 | c.727A>C p.M243L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99997276; called by muse, mutect2, varscan2
- WNT9A | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs765889724, COSV55294318, COSV55294393; called by muse, mutect2, varscan2
- AC011005.1 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 120/274 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, varscan2
- BTBD8 | c.5318C>G p.S1773C (on ENST00000636805 / NM_001376131.1; = p.S1260C on NM_015237.4) | Missense Mutation (SNP) | VAF 25/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- BTNL2 | c.236A>C p.D79A | Missense Mutation (SNP) | VAF 10/285 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.13); called by muse, mutect2
- CASKIN1 | c.1586T>C p.I529T | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CHD9 | c.7876G>A p.E2626K (on ENST00000398510 / NM_001382353.1; = p.E2610K on NM_025134.7) | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.98); called by muse, mutect2
- EXD1 | c.1077T>A p.N359K | Missense Mutation (SNP) | VAF 92/287 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FGD3 | c.2126A>G p.D709G | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GABRE | c.830T>A p.F277Y | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MICAL2 | c.1195A>C p.S399R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- NLRP8 | c.21del p.S8Lfs*38 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- NRP2 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4F15 | c.497T>C p.L166S | Missense Mutation (SNP) | VAF 62/317 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POLR2A | c.2446G>C p.G816R | Missense Mutation (SNP) | VAF 17/331 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- QSER1 | c.4452A>C p.K1484N (on ENST00000399302; = p.K1613N on NM_001076786.3) | Missense Mutation (SNP) | VAF 71/294 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- ROBO2 | c.1601C>T p.T534I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- THOC2 | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 106/233 reads (45%) | called by muse, mutect2, varscan2
- THSD7B | c.1657T>G p.F553V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC17 | c.434T>A p.I145K | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- ZNF257 | c.463T>A p.Y155N | Missense Mutation (SNP) | VAF 71/129 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF836 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- ZNFX1 | c.2664+1G>A p.X888_splice | Splice Site (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- ABCC10 | c.363G>A p.V121= (on ENST00000372530 / NM_001198934.2; = p.V78= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/122 reads (46%) | called by muse, mutect2, varscan2
- AFAP1L1 | c.549C>T p.D183= | Silent (SNP) | VAF 58/145 reads (40%) | catalogued as rs754956697, COSV57044287; called by muse, mutect2, varscan2
- BAIAP2 | c.252G>A p.R84= | Silent (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- CWC25 | c.1277G>A p.*426= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2
- DIP2B | c.45G>A p.A15= | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- DNAH3 | c.10167G>A p.T3389= | Silent (SNP) | VAF 63/126 reads (50%) | catalogued as rs201349145; called by muse, mutect2, varscan2
- EPHB2 | c.2931G>A p.Q977= (on ENST00000400191 / NM_001309193.2; = p.Q978= on NM_004442.7) | Silent (SNP) | VAF 23/407 reads (6%) | called by muse, mutect2
- EPHX2 | c.1251A>G p.L417= | Silent (SNP) | VAF 58/152 reads (38%) | catalogued as rs976652441, COSV66844589; ClinVar: likely benign; called by muse, mutect2, varscan2
- EVPL | c.5388C>A p.I1796= | Silent (SNP) | VAF 107/258 reads (41%) | called by muse, mutect2, varscan2
- FOXN4 | c.408G>A p.P136= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs776629656; called by muse, mutect2
- IGHJ2 | c.36G>T p.L12= | Silent (SNP) | VAF 69/81 reads (85%) | catalogued as rs552325782; called by muse, varscan2
- IGHV2-70 | c.174C>A p.I58= | Silent (SNP) | VAF 43/49 reads (88%) | catalogued as rs371385744; called by muse, varscan2
- ITGAD | c.918G>A p.A306= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs141660381; called by muse, mutect2, varscan2
- ITPRID1 | c.1020A>T p.S340= | Silent (SNP) | VAF 62/132 reads (47%) | called by muse, mutect2, varscan2
- KCNH6 | c.1224C>T p.F408= | Silent (SNP) | VAF 54/156 reads (35%) | catalogued as rs775596369, COSV59008645; called by muse, mutect2, varscan2
- MME | c.348C>T p.V116= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1459481415, COSV64707149; called by muse, mutect2, varscan2
- MYO10 | c.2841C>T p.F947= | Silent (SNP) | VAF 92/295 reads (31%) | catalogued as rs775378841, COSV57017674; called by muse, mutect2, varscan2
- PTPRF | c.861C>T p.L287= | Silent (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- RBFOX2 | c.267C>T p.D89= (on ENST00000438146 / NM_001349995.2; = p.D19= on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 129/325 reads (40%) | catalogued as rs549636175; called by muse, mutect2, varscan2
- SLA | c.630C>T p.D210= (on ENST00000338087 / NM_001045556.3; = p.D250= on NM_006748.4) | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- SLC39A7 | c.495T>C p.H165= | Silent (SNP) | VAF 41/108 reads (38%) | called by muse, mutect2, varscan2
- SMYD2 | c.1101T>C p.I367= | Silent (SNP) | VAF 76/119 reads (64%) | called by muse, mutect2, varscan2
- TENM1 | c.5832T>G p.T1944= | Silent (SNP) | VAF 88/90 reads (98%) | called by muse, mutect2, varscan2
- TLR5 | c.1260G>A p.K420= | Silent (SNP) | VAF 30/244 reads (12%) | catalogued as COSV60558562; called by muse, mutect2, varscan2
- UNC13D | c.1009C>T p.L337= | Silent (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- ZNF335 | c.1065G>A p.R355= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs147453890; called by muse, mutect2, varscan2
- AASS | c.2396+135G>A | Intron (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- AC093909.6 | chr4:188739376 C>A | 3'Flank (SNP) | VAF 18/173 reads (10%) | called by muse, mutect2, varscan2
- AMOTL1 | c.*3300G>T | 3'UTR (SNP) | VAF 94/160 reads (59%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.*105T>C | 3'UTR (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.*1358C>T | 3'UTR (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- CD200R1L | c.-43A>C | 5'UTR (SNP) | VAF 152/257 reads (59%) | called by muse, mutect2, varscan2
- CFB | c.897+42G>A | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as rs1275191401; called by muse, mutect2
- COL18A1 | c.*155G>T | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- CRP | c.*34T>G | 3'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- CTSE | c.*487T>C | 3'UTR (SNP) | VAF 24/85 reads (28%) | catalogued as rs1553276618; called by muse, mutect2, varscan2
- CXADR | c.*3657G>T | 3'UTR (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- DENND6A | c.*567C>T | 3'UTR (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- DMAP1 | c.1344+49C>T | Intron (SNP) | VAF 3/38 reads (8%) | catalogued as rs1482458600; called by muse, mutect2
- EIF2S2 | c.*964G>A | 3'UTR (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- GFRA3 | c.*187T>A | 3'UTR (SNP) | VAF 21/80 reads (26%) | catalogued as rs1416706747; called by muse, mutect2, varscan2
- GPSM3 | c.*59C>T | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- GULP1 | c.844-2970T>C | Intron (SNP) | VAF 19/30 reads (63%) | called by muse, mutect2, varscan2
- IREB2 | c.*824T>A | 3'UTR (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- KCNH5 | c.*883A>T | 3'UTR (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- KCNJ3 | c.*2871T>G | 3'UTR (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- KNDC1 | c.*1140T>A | 3'UTR (SNP) | VAF 11/197 reads (6%) | called by muse, mutect2
- LINGO1-AS1 | n.285G>C | RNA (SNP) | VAF 141/221 reads (64%) | called by muse, mutect2, varscan2
- LPGAT1 | chr1:211745754 C>T | 3'Flank (SNP) | VAF 48/235 reads (20%) | called by muse, mutect2, varscan2
- LRRC6 | c.1144+1709C>T | Intron (SNP) | VAF 70/182 reads (38%) | called by muse, mutect2, varscan2
- MS4A1 | c.*2178dup | 3'UTR (INS) | VAF 60/129 reads (47%) | called by mutect2, pindel, varscan2
- MYO5A | c.*3979A>C | 3'UTR (SNP) | VAF 22/263 reads (8%) | called by muse, mutect2
- NAALADL2 | c.*585A>C | 3'UTR (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- NALCN | c.*1283T>G | 3'UTR (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- NDUFA10 | c.*982T>G | 3'UTR (SNP) | VAF 55/130 reads (42%) | called by muse, mutect2, varscan2
- PDE10A | c.*5271T>G | 3'UTR (SNP) | VAF 20/24 reads (83%) | called by muse, mutect2, varscan2
- PHYH | c.*405T>C | 3'UTR (SNP) | VAF 42/110 reads (38%) | called by muse, mutect2, varscan2
- PHYKPL | c.339-78G>C | Intron (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- PRMT8 | c.-400A>C | 5'UTR (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
- RAB3IP | c.*872A>G | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2
- RFPL1 | c.*169T>G | 3'UTR (SNP) | VAF 104/240 reads (43%) | called by muse, mutect2, varscan2
- RNF141 | c.*2753G>A | 3'UTR (SNP) | VAF 34/163 reads (21%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*254G>T | 3'UTR (SNP) | VAF 20/41 reads (49%) | catalogued as COSV99753506; called by muse, mutect2, varscan2
- RUNX1T1 | c.-86+4413C>T | Intron (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- SGCD | c.*4665T>A | 3'UTR (SNP) | VAF 68/90 reads (76%) | called by muse, mutect2, varscan2
- SGCZ | c.*461T>G | 3'UTR (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2
- SMAD2 | c.*9718T>C | 3'UTR (SNP) | VAF 40/75 reads (53%) | called by muse, mutect2, varscan2
- SOX6 | chr11:15971819 ins A | 3'Flank (INS) | VAF 30/108 reads (28%) | called by mutect2, varscan2
- SYBU | c.*696T>G | 3'UTR (SNP) | VAF 23/47 reads (49%) | called by muse, varscan2
- SYBU | c.*611T>G | 3'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, varscan2
- TAB3 | c.*659C>G | 3'UTR (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- TBC1D30 | c.*2366dup | 3'UTR (INS) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- TFEC | c.*3623A>G | 3'UTR (SNP) | VAF 24/76 reads (32%) | catalogued as rs899650090; called by muse, mutect2, varscan2
- TMEM144 | c.*92T>G | 3'UTR (SNP) | VAF 98/215 reads (46%) | called by muse, varscan2
- TMEM151A | c.*115C>T | 3'UTR (SNP) | VAF 72/135 reads (53%) | called by muse, mutect2, varscan2
- TMEM182 | c.*938C>T | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- TMEM232 | c.*420T>G | 3'UTR (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- TNFRSF10C | c.*72C>T | 3'UTR (SNP) | VAF 62/158 reads (39%) | catalogued as rs927486780; called by muse, mutect2, varscan2
- TRIM6 | c.*1128G>A | 3'UTR (SNP) | VAF 81/182 reads (45%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*1324C>G | 3'UTR (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- UCK1 | c.603+101T>C | Intron (SNP) | VAF 20/63 reads (32%) | catalogued as rs747414924; called by muse, mutect2
- ZDHHC8 | c.*983G>A | 3'UTR (SNP) | VAF 3/11 reads (27%) | catalogued as rs1425026689; called by muse, mutect2
- ZEB2 | c.73+3302A>G | Intron (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- ZNF503-AS2 | n.1727G>C | RNA (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
